Somatic mutation profile of tumor specimen 0DOV98 from CCDI case PBCCYI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,409 days).
Specimen 0DOV98: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40254d6f-f959-451d-895e-0596c3bbcecb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ddcd7f1-cd6a-4da2-a339-a42a376ecb60

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 5'UTR 1, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/593 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NDST4 | c.1066+1G>T p.X356_splice | Splice Site (SNP) | VAF 56/545 reads (10%) | called by muse, mutect2, varscan2
- ZBTB1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 20/518 reads (4%) | called by muse, mutect2
- ZGRF1 | c.6102G>C p.L2034F | Missense Mutation (SNP) | VAF 31/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FAM47B | c.324G>A p.S108= | Silent (SNP) | VAF 137/814 reads (17%) | catalogued as COSV61452731; called by muse, mutect2, varscan2
- KLHL13 | c.6A>G p.P2= | Silent (SNP) | VAF 62/656 reads (9%) | called by muse, mutect2
- AJUBA | c.*31C>G | 3'UTR (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- RHOH | c.-50C>A | 5'UTR (SNP) | VAF 5/84 reads (6%) | catalogued as rs1250866104; called by muse, mutect2
